Gene-level copy-number profile of tumor specimen TCGA-D3-A2J8-06A from TCGA case TCGA-D3-A2J8, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 53.0 years (19,363 days).
Specimen TCGA-D3-A2J8-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.66577e4f-e9ff-4e78-b845-d3f4aafe1f8a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A2J8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2d941a72-a87b-4275-8194-692dba600ca4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 576; copy number 2: 52,077; copy number 3: 4,087; copy number 4: 2,297; copy number 5: 783.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A2J8-06A-11D-A194-01): tumor purity 0.21, ploidy 2.19, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 783 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:213,983,181–248,919,946, 762 genes, copy number 5 (broad region; genes not listed).
- chr3:160,495,007–160,565,571, 1 gene, copy number 5 (within-gene range 4–5): KPNA4.
- chr3:160,565,447–162,601,792, 20 genes, copy number 5: KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC112770.1, AC131211.1, TOMM22P6, AC128716.1.

Autosomal genes at a single copy (total copy number 1): 576. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
